Surgical pathology report (de-identified scan), TCGA case TCGA-B6-A0IQ, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Duke, specimen TCGA-B6-A0IQ-01A (Primary Tumor).

[page 1 of 2]
Patient

Surgical Pathology

Surg Path

CLINICAL HISTORY:

Infiltrating ductal cancer by incisional biopsy.

GROSS EXAMINATION:

A. "Left breast". Received fresh is a 600 gram, 17 x 14 x 4 cm breast with a 7 x 5 x 2.5 cm axillary tail. There is a 15 x 10 cm skin ellipse with a 4 cm in diameter areolar and a 1 cm in diameter nipple. 5 cm superior and lateral to the nipple is a 2.5 cm well-healed scar. On cut section, a 5.5 x 4 x 3.5 cm firm tan-white mass lies deep to the skin incision. Within the mass is a 1 x 1 x 1 cm hemorrhagic capsule. The mass appears well-circumscribed but approaches to within 2 mm of the deep margin. No other lesions are noted.

BLOCK SUMMARY:

- A1-A2- nipple.
- A3- scar and previous biopsy capsule.
- A4-A5- representative sections of tumor.
- A6-A7- deep margin.
- A8- upper inner quadrant.
- A9- lower inner quadrant.
- A10- lower outer quadrant.
- A11- upper outer quadrant.
- A12- six lymph node candidates, proximal third.
- A13- five lymph node candidates, middle third.
- A14- five lymph node candidates, distal third.
- A15- four lymph node candidates, distal third.
- A16- four lymph node candidates, distal third.

NIHAA Discrepancy		

B. "Rotter's node". Received fresh is a 1.2 x 0.7 x 0.5 cm firm node which is bisected and submitted in toto in Block B1.

MICROSCOPIC EXAMINATION:

The carcinoma is growing as rounded masses composed of nests and trabeculae of carcinoma. There is extensive necrosis. 10 mitoses per 10 high power fields are present. The pattern of growth makes it difficult to be certain what is invasive and what is in-situ with cancerization of the lobules.

DIAGNOSIS:

A. "LEFT BREAST" (MASTECTOMY):

BREAST WITH RESIDUAL INFILTRATING DUCTAL CARCINOMA, NSABP HISTOLOGIC GRADE 3, NUCLEAR GRADE MODERATELY-DIFFERENTIATED.

SIZE IS 5.5 X 4 X 3.5 CM. INCLUDING PRIOR BIOPSY CAVITY.

LESS THAN 5% IDENTIFIABLE AS INTRADUCTAL CARCINOMA, SOLID AND COMEDO TYPES.

THE CARCINOMA IS WITHIN 1 MM OF THE DEEP MARGIN.

NO LYMPHATIC INVASION IS SEEN.

BENIGN CHANGES OF THE BREAST INCLUDING APOCRINE METAPLASIA AND DUCT ECTASIA.

NIPPLE WITH NO PATHOLOGIC DIAGNOSIS.

26 LYMPH NODES WITH NO EVIDENCE OF MALIGNANCY.

B. "ROTTER'S NODE" (EXCISION):

[page 2 of 2]
ONE LYMPH NODE, POSITIVE FOR CARCINOMA.

Verified by:

Source: NCI Genomic Data Commons file c166bf27-bdbc-4b72-b38a-78b2d7f78a7e (TCGA-B6-A0IQ.0ED7357E-662C-4D65-82ED-29739919068F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).